Somatic mutation profile of tumor specimen 0DXXXZ from CCDI case PBCRXY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.4 years (3,079 days).
Specimen 0DXXXZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 373116a7-211d-46e1-99c1-eb8136466841.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXXWC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1db71a3d-0dfd-405c-bb00-18604f0e6fc5

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 4, Intron 2, Frame Shift Del 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KBTBD4 | c.884_886dup p.P295dup | In Frame Ins (INS) | VAF 348/967 reads (36%) | catalogued as COSV58596732, COSV58597734, COSV58597899; called by mutect2, pindel, varscan2
- NFATC2 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 76/631 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs757310570, COSV65352893; called by muse, mutect2, varscan2
- PTEN | c.388del p.R130Efs*4 | Frame Shift Del (DEL) | VAF 432/911 reads (47%) | catalogued as CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; called by mutect2, pindel, varscan2
- SERPINA5 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 385/852 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.142); catalogued as rs373021004; called by muse, mutect2, varscan2
- LST1 | c.289T>C p.C97R | Missense Mutation (SNP) | VAF 521/1180 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- MCRS1 | c.977G>A p.W326* | Nonsense Mutation (SNP) | VAF 399/885 reads (45%) | called by muse, mutect2, varscan2
- WTIP | c.972C>A p.D324E | Missense Mutation (SNP) | VAF 41/780 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- AGFG2 | c.942C>T p.L314= | Silent (SNP) | VAF 60/1806 reads (3%) | catalogued as rs761358790; called by muse, mutect2
- ATRNL1 | c.3804T>G p.L1268= | Silent (SNP) | VAF 125/1005 reads (12%) | catalogued as COSV58093818; called by muse, mutect2, varscan2
- ENPP7 | c.261T>C p.Y87= | Silent (SNP) | VAF 594/1593 reads (37%) | catalogued as rs1393155432; called by muse, mutect2, varscan2
- GOLGA5 | c.741G>A p.S247= | Silent (SNP) | VAF 564/1265 reads (45%) | catalogued as rs747227189, COSV50834331; called by muse, mutect2, varscan2
- RBM45 | c.989+30C>A | Intron (SNP) | VAF 241/457 reads (53%) | called by muse, mutect2, varscan2
- SLC47A2 | c.1017+34C>T | Intron (SNP) | VAF 290/633 reads (46%) | called by muse, mutect2, varscan2
